Somatic mutation profile of tumor specimen TCGA-EA-A3HQ-01A (aliquot TCGA-EA-A3HQ-01A-11D-A20U-09) from TCGA case TCGA-EA-A3HQ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage II; Tumor grade: G2; Age at diagnosis: 60.1 years (21,966 days).
Specimen TCGA-EA-A3HQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ced74490-4133-4433-9bc3-cbe0b1e6e707.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EA-A3HQ-10A (Blood Derived Normal), aliquot TCGA-EA-A3HQ-10A-01D-A20U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b79ead83-dd2c-4ab4-b2b0-21c187904226

The open-access MAF lists 103 somatic variants for this specimen: 73 protein-altering or splice-affecting, 28 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 28, Nonsense Mutation 7, Frame Shift Del 2, RNA 2, In Frame Del 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.4800_4803del p.S1601Ffs*7 | Frame Shift Del (DEL) | VAF 27/59 reads (46%) | catalogued as rs1060501659; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- EP300 | c.1942C>T p.R648* | Nonsense Mutation (SNP) | VAF 39/52 reads (75%) | catalogued as rs137853039, CM052869, COSV54332975; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 41/108 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- LRP5 | c.3758G>A p.C1253Y | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768615287, CM103444, COSV53721081, COSV99591892; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1499-1G>C p.X500_splice | Splice Site (SNP) | VAF 16/24 reads (67%) | hotspot (GDC flag); catalogued as CS011568, CS941539, COSV57296073, COSV57310062, COSV57310173; called by muse, mutect2, varscan2
- ADGRF4 | c.1117G>T p.E373* | Nonsense Mutation (SNP) | VAF 49/121 reads (40%) | catalogued as rs771530266, COSV51951749, COSV51955542; called by muse, mutect2, varscan2
- AFAP1L2 | c.1648C>T p.P550S | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV58417509; called by muse, mutect2, varscan2
- AP3B1 | c.1091del p.R364Kfs*9 | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | catalogued as COSV54880967; called by mutect2, pindel, varscan2
- APLP1 | c.1658C>T p.A553V (on ENST00000221891 / NM_001024807.3; = p.A552V on NM_005166.4) | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1156249745, COSV55705407; called by muse, mutect2, varscan2
- ARHGAP35 | c.1387G>T p.D463Y | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV68334167; called by muse, mutect2, varscan2
- BBX | c.794G>A p.C265Y | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.824); catalogued as COSV57891293; called by muse, mutect2, varscan2
- C1orf43 | c.244G>A p.D82N (on ENST00000368521 / NM_001297718.2; = p.D48N on NM_015449.4) | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV62966952; called by muse, mutect2, varscan2
- C1orf94 | c.851C>A p.T284K (on ENST00000488417 / NM_001134734.2; = p.T94K on NM_032884.5) | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.038); catalogued as COSV64914942; called by muse, mutect2, varscan2
- C3orf20 | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.121); catalogued as rs762741326, COSV53787970; called by muse, mutect2, varscan2
- CACNA1F | c.4803A>T p.E1601D | Missense Mutation (SNP) | VAF 59/81 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV59906221; called by muse, mutect2, varscan2
- CAGE1 | c.1600C>T p.Q534* (on ENST00000512086; = p.Q398* on NM_205864.3) | Nonsense Mutation (SNP) | VAF 22/60 reads (37%) | catalogued as COSV57080289; called by muse, mutect2, varscan2
- CALCOCO1 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs371310406; called by muse, mutect2, varscan2
- CDK12 | c.2752G>A p.D918N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71002155; called by muse, mutect2, varscan2
- CHAT | c.1157G>T p.C386F | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.065); catalogued as COSV60329933; called by muse, mutect2, varscan2
- CHST5 | c.427T>C p.F143L | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60340933; called by muse, mutect2, varscan2
- CIRBP | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs1215211863, COSV58011863; called by muse, mutect2, varscan2
- CLSTN1 | c.1670G>C p.C557S (on ENST00000377298 / NM_001009566.3; = p.C547S on NM_014944.4) | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV63650124; called by muse, mutect2, varscan2
- COL27A1 | c.2807C>T p.P936L | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs764037280, COSV61929470; called by muse, mutect2, varscan2
- COLEC12 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 68/180 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as rs146515222; called by muse, mutect2, varscan2
- DISP2 | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs201542979, COSV51134343; called by muse, mutect2
- EXTL1 | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs746185482, COSV65338104; called by muse, mutect2, varscan2
- FKBP10 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 49/55 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs782653042, CM130012, COSV58638284; called by muse, mutect2, varscan2
- GHR | c.92G>C p.R31T | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.027); catalogued as COSV50122755; called by muse, mutect2, varscan2
- GPR3 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.044); catalogued as COSV64995087; called by muse, mutect2, varscan2
- GPR39 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV61415993; called by muse, mutect2, varscan2
- GPR45 | c.607G>A p.V203M | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.714); catalogued as rs560190604, COSV51522761, COSV51523162; called by muse, mutect2, varscan2
- HAO1 | c.575C>G p.S192* | Nonsense Mutation (SNP) | VAF 15/24 reads (63%) | catalogued as COSV66490836, COSV66491086; called by muse, mutect2, varscan2
- IFT80 | c.2188G>A p.E730K | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as rs760611602, COSV58450763; called by muse, mutect2, varscan2
- IGF2R | c.4019C>T p.P1340L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63631476; called by muse, mutect2, varscan2
- INSR | c.3799G>T p.D1267Y | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV57169737; called by muse, mutect2, varscan2
- KANSL1 | c.2857C>T p.R953W (on ENST00000574590 / NM_001193465.2; = p.R954W on NM_015443.4) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as rs1322831151, COSV52245239; called by muse, mutect2, varscan2
- KLHDC1 | c.1168A>G p.R390G | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.025); catalogued as COSV104420976, COSV63779142; called by muse, mutect2, varscan2
- KMT2D | c.6973G>A p.D2325N | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as COSV56470788; called by muse, mutect2, varscan2
- L3MBTL1 | c.1926G>A p.R642= (on ENST00000418998 / NM_001377303.1; = p.R552= on NM_015478.7) | Splice Region (SNP) | VAF 47/75 reads (63%) | catalogued as rs1225100698, COSV100917031; called by muse, mutect2, varscan2
- LPA | c.3036C>A p.C1012* | Nonsense Mutation (SNP) | VAF 48/124 reads (39%) | catalogued as rs1051416677, COSV100307615; called by muse, varscan2
- MIA3 | c.2893G>A p.E965K | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV100719214, COSV60516115; called by muse, mutect2, varscan2
- MLF1 | c.493C>T p.H165Y | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs942620752, COSV63034822; called by muse, mutect2
- NAA15 | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as COSV56720030, COSV56721618; called by muse, mutect2, varscan2
- NAP1L3 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59076968; called by muse, mutect2, varscan2
- OR6K2 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs532035184, COSV62743770; called by muse, mutect2, varscan2
- PCDH9 | c.3446G>A p.G1149D (on ENST00000377865 / NM_203487.3; = p.G1115D on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/77 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1336069735, COSV60576414; called by muse, mutect2, varscan2
- PELI2 | c.275A>G p.E92G | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs1010145702, COSV50714156; called by muse, mutect2, varscan2
- PHF12 | c.316C>G p.R106G | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as rs1567962699, COSV52018035, COSV52021104; called by muse, mutect2, varscan2
- PID1 | c.209A>C p.E70A (on ENST00000354069 / NM_001330156.1; = p.E68A on NM_017933.5) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as COSV62480007; called by muse, mutect2, varscan2
- PLXNA2 | c.5527G>T p.E1843* | Nonsense Mutation (SNP) | VAF 54/151 reads (36%) | catalogued as COSV65443405; called by muse, mutect2, varscan2
- PNPO | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 44/54 reads (81%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as rs1308221954, COSV56666104; called by muse, mutect2, varscan2
- PPP1R7 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.114); catalogued as COSV52146282; called by muse, mutect2, varscan2
- PRAMEF12 | c.1057C>G p.L353V | Missense Mutation (SNP) | VAF 110/380 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV63216172; called by muse, mutect2, varscan2
- PRB4 | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.029); catalogued as COSV54398920; called by muse, varscan2
- PRDM14 | c.1574C>G p.S525C | Missense Mutation (SNP) | VAF 104/205 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV52574594; called by muse, mutect2, varscan2
- RBPJL | c.1258G>A p.V420M | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as COSV59213219; called by muse, mutect2, varscan2
- RSPH4A | c.1948C>T p.H650Y | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.834); catalogued as COSV57636117; called by muse, mutect2, varscan2
- RSPO2 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52638484; called by muse, mutect2, varscan2
- RYR3 | c.12019G>A p.D4007N (on ENST00000389232; = p.D4008N on NM_001036.6) | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs756925363, COSV66803113; called by muse, mutect2, varscan2
- SH3KBP1 | c.1405G>A p.V469M | Missense Mutation (SNP) | VAF 68/88 reads (77%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs763646545, COSV65648898; called by muse, mutect2, varscan2
- SIPA1 | c.803C>T p.T268M | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV63136932; called by muse, mutect2, varscan2
- SLC25A42 | c.37C>A p.H13N | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV59381285; called by muse, mutect2, varscan2
- STRA6 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 47/174 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV60587765; called by muse, mutect2, varscan2
- SYT7 | c.907G>T p.D303Y | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs567302490, COSV55658135; called by muse, mutect2, varscan2
- TEPSIN | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 68/113 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as rs758539478, COSV56144165; called by muse, mutect2, varscan2
- TRPV4 | c.779A>G p.Q260R | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as COSV55684209; called by muse, mutect2, varscan2
- TTN | c.35596C>T p.R11866C (on ENST00000591111; = p.R4442C on NM_003319.4) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | PolyPhen benign (0.123); catalogued as rs528749203, COSV59936462; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- TTN | c.17775C>A p.S5925R (on ENST00000591111; = p.S4998R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | PolyPhen possibly damaging (0.654); catalogued as COSV60240500; called by mutect2, varscan2
- VAV2 | c.1414G>A p.G472R | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs935532382, COSV64084101; called by muse, mutect2, varscan2
- ZNF711 | c.1222C>T p.H408Y | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as rs1170676581, COSV52151615; called by muse, mutect2, varscan2
- CATSPER1 | c.834_836del p.H279del | In Frame Del (DEL) | VAF 118/358 reads (33%) | called by pindel, varscan2
- CATSPER1 | c.696_704del p.E233_H235del | In Frame Del (DEL) | VAF 60/168 reads (36%) | called by mutect2, pindel, varscan2
- POLR2A | c.4873A>G p.T1625A | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- ABHD2 | c.843G>A p.K281= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV61775564, COSV61776150; called by muse, mutect2, varscan2
- AFF3 | c.705G>A p.V235= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as COSV100420446, COSV57874259; called by muse, mutect2, varscan2
- APP | c.1650C>T p.N550= | Silent (SNP) | VAF 28/51 reads (55%) | catalogued as rs201877705; ClinVar: likely benign; called by muse, mutect2, varscan2
- BSN | c.9420C>T p.A3140= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV56523209; called by muse, mutect2, varscan2
- C1orf43 | c.309G>A p.R103= (on ENST00000368521 / NM_001297718.2; = p.R69= on NM_015449.4) | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV62966661; called by muse, mutect2, varscan2
- C3 | c.1998C>T p.A666= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs373167228; called by muse, mutect2, varscan2
- CCNF | c.1335C>T p.S445= | Silent (SNP) | VAF 22/35 reads (63%) | catalogued as rs529445674, COSV53541986; ClinVar: likely benign; called by muse, mutect2, varscan2
- CENPV | c.798C>T p.I266= | Silent (SNP) | VAF 52/107 reads (49%) | catalogued as rs547635883, COSV55333837; called by muse, mutect2, varscan2
- CORIN | c.2091C>T p.N697= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV56696466; called by muse, mutect2, varscan2
- DSCAML1 | c.3600C>T p.G1200= (on ENST00000321322; = p.G1140= on NM_020693.4) | Silent (SNP) | VAF 45/107 reads (42%) | catalogued as rs778954194, COSV58398646; called by muse, mutect2, varscan2
- GFPT2 | c.606C>T p.S202= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as COSV53811082, COSV99518040; called by muse, mutect2, varscan2
- INAVA | c.105G>A p.A35= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV66255826; called by muse, mutect2, varscan2
- INTS1 | c.1680C>T p.A560= | Silent (SNP) | VAF 38/95 reads (40%) | catalogued as rs763175494, COSV67176620, COSV67178931; called by muse, mutect2, varscan2
- LRIF1 | c.903G>A p.T301= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs1430013971, COSV63898109; called by muse, mutect2, varscan2
- MAP3K6 | c.2925G>A p.E975= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV100539480; called by muse, mutect2, varscan2
- MFAP3L | c.912C>T p.D304= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as rs377059924, COSV64371970; called by muse, mutect2, varscan2
- NRXN1 | c.798G>A p.A266= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as rs201027928; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- OPRD1 | c.915G>A p.A305= | Silent (SNP) | VAF 51/145 reads (35%) | catalogued as rs898272507, COSV52381237; called by muse, mutect2
- PELO | c.495G>A p.V165= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV50882036; called by muse, mutect2, varscan2
- PNLDC1 | c.588G>A p.T196= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs1455381246, COSV51705721, COSV51707141; called by muse, mutect2, varscan2
- PNPLA1 | c.1098A>T p.L366= (on ENST00000394571 / NM_001374623.1; = p.L271= on NM_173676.2) | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV57236740; called by muse, mutect2, varscan2
- POSTN | c.2157A>G p.T719= | Silent (SNP) | VAF 33/81 reads (41%) | catalogued as COSV65714017; called by muse, mutect2, varscan2
- SV2C | c.936G>A p.S312= | Silent (SNP) | VAF 121/345 reads (35%) | catalogued as rs200052408, COSV59215465; called by muse, mutect2, varscan2
- TARS2 | c.1731C>T p.A577= | Silent (SNP) | VAF 28/107 reads (26%) | catalogued as COSV60874261; called by muse, mutect2, varscan2
- TENM2 | c.2466G>T p.L822= (on ENST00000518659 / NM_001122679.2; = p.L590= on NM_001080428.3) | Silent (SNP) | VAF 36/107 reads (34%) | catalogued as COSV69137536; called by muse, mutect2, varscan2
- TEX15 | c.7236G>A p.S2412= (on ENST00000256246; = p.S2795= on NM_001350162.2) | Silent (SNP) | VAF 33/145 reads (23%) | catalogued as rs371955113; called by muse, mutect2, varscan2
- TSPEAR | c.1818C>T p.F606= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as rs1205316092, COSV59970327; called by muse, mutect2, varscan2
- UNC93A | c.525G>A p.T175= | Silent (SNP) | VAF 58/143 reads (41%) | catalogued as rs778404146, COSV100023543; called by muse, varscan2
- ATP6AP1L | n.1724A>C | RNA (SNP) | VAF 29/67 reads (43%) | catalogued as COSV66475363; called by muse, mutect2, varscan2
- XIST | n.7384C>A | RNA (SNP) | VAF 30/54 reads (56%) | called by muse, mutect2, varscan2
